Somatic mutation profile of tumor specimen TCGA-A2-A0D4-01A (aliquot TCGA-A2-A0D4-01A-11W-A019-09) from TCGA case TCGA-A2-A0D4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 37.8 years (13,805 days).
Specimen TCGA-A2-A0D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4032f485-0d9f-47a8-90f6-6918c71696dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0D4-10A (Blood Derived Normal), aliquot TCGA-A2-A0D4-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1aefc1d-4c17-4869-932c-8118aa8c1e71

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, Intron 1, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS2 | c.1569C>A p.H523Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs760600379, COSV58191556; called by muse, mutect2, varscan2
- ARHGAP35 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs778118639, COSV101351570; called by muse, mutect2
- AVPR1A | c.871A>G p.K291E | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54547091; called by muse, mutect2
- C1QTNF7 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs199762846; called by muse, mutect2
- CAMSAP3 | c.3361A>C p.N1121H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50338019; called by muse, mutect2
- CD1C | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV100939413, COSV63805980; called by muse, mutect2, varscan2
- DDX20 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs746185964, COSV63779784; called by muse, mutect2
- DNHD1 | c.13385G>A p.R4462H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV54438294; called by muse, mutect2, varscan2
- FAM90A1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV56712233, COSV56712922; called by muse, mutect2, varscan2
- GSDMC | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 41/531 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs754298748, COSV52693400; called by muse, mutect2
- GUCY2F | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV54304459; called by muse, mutect2, varscan2
- HEG1 | c.1527G>T p.E509D | Missense Mutation (SNP) | VAF 54/515 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100230883; called by muse, mutect2, varscan2
- INTS14 | c.1503G>C p.Q501H (on ENST00000313182 / NM_001366360.2; = p.Q422H on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1487858962, COSV99971278; called by muse, mutect2
- IQCB1 | c.1108A>G p.M370V | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as rs112790935, COSV60438136; called by muse, mutect2, varscan2
- IQCH | c.2825T>C p.L942S | Missense Mutation (SNP) | VAF 255/317 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60055026; called by muse, mutect2, varscan2
- JPH1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV60612146; called by muse, mutect2
- KIF3C | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53100167; called by muse, mutect2, varscan2
- MED23 | c.1597G>T p.V533F | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV63433518; called by muse, mutect2, varscan2
- N4BP2L2 | c.2194C>T p.H732Y (on ENST00000674422; = p.H303Y on NM_033111.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV62633535; called by muse, mutect2, varscan2
- NBEAL1 | c.4433G>T p.G1478V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV71374700; called by muse, mutect2, varscan2
- PABPC5 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57041542; called by muse, mutect2, varscan2
- PCDHA5 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1554129247, COSV65350227; called by muse, mutect2, varscan2
- PRKACG | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99599602; called by muse, mutect2
- RTL3 | c.1280A>T p.N427I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV58184548; called by muse, mutect2, varscan2
- SLC24A4 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV54115423; called by muse, mutect2, varscan2
- SPTBN4 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs760167885, COSV58952820; called by muse, mutect2, varscan2
- TEP1 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 157/260 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52994728; called by muse, mutect2, varscan2
- UNC13B | c.2542G>T p.A848S | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV101037181; called by muse, mutect2
- HDAC7 | c.552dup p.S185Qfs*17 (on ENST00000427332; = p.S224Qfs*17 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- PDS5A | c.3886_3911del p.R1296Efs*9 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- CPA1 | c.1107C>T p.Y369= | Silent (SNP) | VAF 173/392 reads (44%) | catalogued as COSV50571060; called by muse, mutect2, varscan2
- KTN1 | c.2235G>A p.K745= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV63215672; called by muse, mutect2, varscan2
- MACF1 | c.16170C>G p.L5390= (on ENST00000372915; = p.L3323= on NM_012090.5) | Silent (SNP) | VAF 43/272 reads (16%) | catalogued as COSV57128189; called by muse, mutect2, varscan2
- MUC17 | c.1956T>A p.T652= | Silent (SNP) | VAF 174/425 reads (41%) | catalogued as COSV60292847; called by muse, mutect2, varscan2
- SLC4A10 | c.480T>G p.A160= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV55784777, COSV99764930; called by muse, mutect2, varscan2
- ACKR1 | c.*1T>C | 3'UTR (SNP) | VAF 14/352 reads (4%) | catalogued as COSV100929645; called by muse, mutect2
- KIF1B | c.2115+7075C>G | Intron (SNP) | VAF 16/448 reads (4%) | catalogued as COSV55810778; called by muse, mutect2
